Gene-level copy-number profile of tumor specimen MP2PRT-PATDRM-TMP1-A from MP2PRT case MP2PRT-PATDRM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,542 days).
Specimen MP2PRT-PATDRM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6eaaac1c-bb07-40d6-b577-4e28975af09e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATDRM-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,270 have no estimate.
https://portal.gdc.cancer.gov/files/f845f5de-582c-481d-a3b7-006543bed762

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 426; copy number 2: 54,690; copy number 3: 821; copy number 4: 2,400; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,257,879–38,265,678, 1 gene (within-gene range 0–1): TRGC1.
- chr7:38,291,616–38,318,861, 5 genes (within-gene range 0–1): TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–1): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–1): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–1): IGHV3-43.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:145,002,811–145,066,685, 4 genes, copy number 5 (within-gene range 4–5): ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.

Autosomal genes at a single copy (total copy number 1): 374. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
